CCDI case PBCVFZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/550229e3-8f02-4c99-a61d-751abaf0714a

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Sample 0E0KXT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E0KYB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
